Gene-level copy-number profile of tumor specimen TCGA-EB-A5SF-01A from TCGA case TCGA-EB-A5SF, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Nodular melanoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 78.8 years (28,772 days).
Specimen TCGA-EB-A5SF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.ad5a22f5-04b3-47d9-8b93-8bdce62c7ced.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EB-A5SF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 819 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/668f4447-9747-4a46-b8e1-49ca5a7d8861

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 24,543; copy number 2: 33,390; copy number 3: 1,161; copy number 4: 133; copy number 5: 103; copy number 6: 118; copy number 7: 65; copy number 8: 87; copy number 9: 8; copy number 10: 49; copy number 11: 3; copy number 12: 75; copy number 13: 30; copy number 16: 16; copy number 17: 8; copy number 18: 9; copy number 19: 2; copy number 21: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EB-A5SF-01A-11D-A30W-01): tumor purity 0.61, ploidy 1.74, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 577 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:117,143,587–121,580,524, 98 genes, copy number 5–16 (within-gene range 1–16) (broad region; genes not listed).
- chr1:148,739,379–149,754,710, 30 genes, copy number 6: RNU6-1171P, NUDT4B, SEC22B3P, AC245389.1, PDE4DIP, RN7SKP88, RNU2-38P, AC239802.1, AC239802.2, AC239804.1, NBPF9, AC239804.2, RNVU1-24, AC245297.3, AC245297.1, AC245297.2, 7SK, SEC22B2P, NOTCH2NLC, AC242842.3, NBPF19, PPIAL4C, LINC00869, AC242842.2, AC242842.1, RNVU1-30, FAM91A2P, AC243772.3, RNU1-68P, AC243772.1.
- chr5:58,198–1,611,467, 60 genes, copy number 5–10: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, AC026740.2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, AC026748.7, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075, AC091849.2, SDHAP3, AC026412.3, AC091849.1.
- chr5:1,614,836–1,616,334, 1 gene, copy number 10: AC026412.2.
- chr5:3,177,835–3,536,094, 4 genes, copy number 6–11: LINC01377, LINC01019, LINC02162, LINC01017.
- chr5:4,012,708–5,320,304, 19 genes, copy number 6–17 (within-gene range 3–17): AC025773.1, AC025187.1, LINC02063, AC106799.3, AC106799.2, AC106799.1, AC010634.1, LINC02114, AC026719.1, AC026415.1, AC010451.3, AC010451.1, LINC01020, AC010451.2, LINC02121, RN7SKP73, CTD-2297D10.2, ADAMTS16, AC022424.1.
- chr5:6,019,029–6,137,171, 3 genes, copy number 5: AC010266.2, AC010266.1, AC026797.1.
- chr5:6,765,891–6,833,120, 1 gene, copy number 5 (within-gene range 3–5): LINC02236.
- chr5:6,827,853–29,600,868, 312 genes, copy number 5–21 (within-gene range 3–21) (broad region; genes not listed).
- chr5:37,106,228–37,249,421, 1 gene, copy number 8 (within-gene range 4–8): CPLANE1.
- chr5:37,209,364–38,845,829, 33 genes, copy number 8: OFD1P17, RN7SL37P, AC025449.2, AC025449.1, NUP155, RNU7-75P, AC117532.1, WDR70, KCTD9P5, RNU6-1190P, RNU6-484P, GDNF-AS1, GDNF, LINC02117, AC008869.1, LINC02110, AC034226.1, LINC02119, AC010338.1, EGFLAM, EGFLAM-AS4, EGFLAM-AS3, EGFLAM-AS2, EGFLAM-AS1, AC091839.1, AC010457.1, LIFR, LIFR-AS1, MIR3650, AC010425.1, OSMR-AS1, AC091435.1, AC091435.2.
- chr5:43,483,913–43,886,628, 12 genes, copy number 5–6: AC114956.2, C5orf34, EEF1A1P19, C5orf34-AS1, AC114956.1, PAIP1, NNT-AS1, AC010435.1, AMD1P3, NNT, RPL29P12, AC104119.1.
- chr5:45,254,948–45,696,498, 3 genes, copy number 16: HCN1, AC117529.2, AC117529.1.

Autosomal genes at a single copy (total copy number 1): 22,122. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
